Somatic mutation profile of tumor specimen MMRF_1682_2_BM_CD138pos (aliquot MMRF_1682_2_BM_CD138pos_T1_KHS5U_L11020) from MMRF case MMRF_1682, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.2 years (26,379 days).
Specimen MMRF_1682_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 371baee9-998e-4826-bff5-3b31e5fbddc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1682_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1682_1_PB_WBC_C3_KBS5U_L05796; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f11a14b3-f44d-4ef6-9c2b-eb891bd7fb54

The open-access MAF lists 252 somatic variants for this specimen: 93 protein-altering or splice-affecting, 27 silent, 132 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, 3'UTR 77, Silent 27, Intron 24, 5'UTR 16, 3'Flank 6, RNA 5, Frame Shift Del 4, 5'Flank 4, Nonsense Mutation 3, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by mutect2, varscan2
- CEP295NL | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs978770019; called by muse, mutect2, varscan2
- CFAP251 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV56612330; called by muse, mutect2, varscan2
- CFAP43 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs145913363, COSV53376560; called by muse, mutect2, varscan2
- CHST7 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52100298; called by muse, mutect2, varscan2
- COL24A1 | c.3807del p.G1270Efs*68 | Frame Shift Del (DEL) | VAF 23/213 reads (11%) | catalogued as rs751232308; called by mutect2, pindel, varscan2
- CSMD3 | c.10660T>G p.L3554V (on ENST00000297405 / NM_001363185.1; = p.L3385V on NM_052900.3) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52339817; called by muse, mutect2, varscan2
- DNAH10 | c.6385G>A p.V2129I (on ENST00000409039; = p.V2068I on NM_207437.3) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs557513283, COSV68992263; called by muse, mutect2, varscan2
- ERCC6L2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.093); catalogued as rs769611647; called by muse, mutect2, varscan2
- GABRG2 | c.208T>G p.L70V | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62717806; called by muse, mutect2, varscan2
- GANC | c.1448A>T p.N483I | Missense Mutation (SNP) | VAF 19/214 reads (9%) | PolyPhen probably damaging (0.984); catalogued as rs201254217; called by muse, mutect2
- GCNT1 | c.693G>C p.R231S | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.276); catalogued as COSV65057005; called by muse, mutect2
- GHRHR | c.844T>A p.W282R | Missense Mutation (SNP) | VAF 31/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58196263; called by muse, mutect2
- GOLGA6L2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs762579164, COSV61479887; called by muse, mutect2
- GRIN2B | c.4009G>A p.A1337T | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs201335987, COSV101663174, COSV74205415, COSV74206068; called by muse, mutect2, varscan2
- GUCY2D | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1322820848; called by muse, mutect2, varscan2
- H1-2 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs553002000, COSV59191114; called by muse, mutect2, varscan2
- IGHV2-70 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576362735; called by muse, varscan2
- INSYN2A | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54738736; called by muse, mutect2, varscan2
- NPR2 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs773576490; called by muse, mutect2
- POU5F2 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 59/367 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs768126763; called by muse, mutect2, varscan2
- RNF183 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as rs373858981; called by muse, mutect2, varscan2
- SSC5D | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1168582762, COSV52700210; called by muse, mutect2
- TAF4B | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99300242; called by muse, mutect2, varscan2
- TTYH2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773763545, COSV53909676; called by muse, mutect2, varscan2
- ZFP42 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750318279, COSV58817208, COSV58818962; called by muse, mutect2, varscan2
- ZNF25 | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs1441702688; called by muse, mutect2
- ZNF804A | c.158T>G p.L53R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56459317; called by muse, mutect2, varscan2
- ADAM28 | c.1433G>T p.C478F | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADH6 | c.1093A>C p.T365P | Missense Mutation (SNP) | VAF 140/500 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- BHLHE41 | c.798_807del p.K266Nfs*12 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- CDC20 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CDC42BPB | c.2414C>A p.A805E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CDH19 | c.1959del p.F654Lfs*3 | Frame Shift Del (DEL) | VAF 45/416 reads (11%) | called by mutect2, pindel, varscan2
- CECR2 | c.4281A>C p.Q1427H (on ENST00000342247 / NM_001290047.2; = p.Q1243H on NM_001290046.1) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP295NL | c.198C>G p.S66R | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CFAP47 | c.4414A>C p.T1472P | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CFHR2 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- CLHC1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL2A1 | c.4343_4344del p.T1448Sfs*16 | Frame Shift Del (DEL) | VAF 21/182 reads (12%) | called by mutect2, varscan2
- CPEB1 | c.371-6A>C | Splice Region (SNP) | VAF 22/179 reads (12%) | called by muse, mutect2, varscan2
- EPS8L3 | c.1112C>A p.T371N | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- FBN3 | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- FILIP1 | c.1317A>C p.E439D | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.1186A>C p.N396H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2
- FYB2 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- GABRB1 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- GREB1 | c.4940C>T p.S1647F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSDL2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.889); called by muse, mutect2
- HSPA12A | c.733T>A p.Y245N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HTR3A | c.1160A>G p.H387R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHA1 | c.827A>T p.Y276F | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); called by muse, mutect2
- IGHV2-70D | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, varscan2
- IGLV4-3 | c.180dup p.R61Efs*10 | Frame Shift Ins (INS) | VAF 51/254 reads (20%) | called by pindel, varscan2*
- ITGA1 | c.1984T>G p.F662V | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2
- ITGA2 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.7); called by mutect2, varscan2
- KDM2A | c.1086T>A p.D362E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KDM4E | c.344T>A p.F115Y | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KLHL1 | c.35A>T p.K12M | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLK2 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- KNDC1 | c.2144T>G p.L715R | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2
- LRIG1 | c.3096C>A p.D1032E | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.053); called by muse, mutect2
- MARF1 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MTF2 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- MUC16 | c.14053T>G p.S4685A | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- NOTCH4 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.141); called by muse, mutect2
- OLR1 | c.218A>C p.N73T | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- OR10A2 | c.530C>A p.A177E | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- OR8K5 | c.920A>T p.N307I | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PCDH10 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 44/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLSCR2 | c.595C>T p.H199Y (on ENST00000497985 / NM_001199978.1; = p.H126Y on NM_020359.2) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PNISR | c.2405C>G p.S802C | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PSEN1 | c.405T>G p.N135K | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMB3 | c.595A>C p.T199P | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- RIMS1 | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- RPTN | c.1288_1323del p.T430_Q441del | In Frame Del (DEL) | VAF 34/615 reads (6%) | called by muse*, mutect2
- SEL1L2 | c.1254C>A p.Y418* | Nonsense Mutation (SNP) | VAF 42/331 reads (13%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.154C>G p.P52A | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOS1 | c.1071_1074+14del p.X357_splice | Splice Site (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel
- SRPX | c.350-2A>C p.X117_splice | Splice Site (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- TAP2 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.012); called by muse, mutect2
- TBX5 | c.1177C>A p.L393I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TIMELESS | c.3472A>T p.K1158* | Nonsense Mutation (SNP) | VAF 41/259 reads (16%) | called by muse, mutect2, varscan2
- TOR4A | c.503T>A p.V168E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TPM2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- TPM2 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TTN | c.51670T>A p.Y17224N (on ENST00000591111; = p.Y9800N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TTN | c.19552G>T p.A6518S (on ENST00000591111; = p.A5591S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- UHRF1BP1 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- WEE2 | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZDBF2 | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF251 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF26 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACE | c.2157G>C p.R719= | Silent (SNP) | VAF 28/332 reads (8%) | called by muse, mutect2
- ARHGAP12 | c.1332A>G p.E444= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- ATP6V1FNB | c.48G>A p.K16= | Silent (SNP) | VAF 30/244 reads (12%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.1926G>A p.P642= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1295505392; called by muse, mutect2, varscan2
- CD36 | c.1323T>A p.L441= | Silent (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2
- CREG2 | c.63C>T p.C21= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- CYP4F3 | c.910C>T p.L304= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- CYP4Z1 | c.1323C>A p.A441= | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- EMILIN2 | c.1053C>T p.L351= | Silent (SNP) | VAF 13/170 reads (8%) | catalogued as rs776880244, COSV54423905; called by muse, mutect2
- FAM102A | c.136T>C p.L46= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- HMCN1 | c.10716G>C p.T3572= | Silent (SNP) | VAF 23/308 reads (7%) | called by muse, mutect2
- KALRN | c.2436G>A p.Q812= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as COSV53774257; called by muse, mutect2, varscan2
- KRT40 | c.1107C>T p.N369= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs761690943; called by muse, mutect2, varscan2
- NANOS1 | c.483G>A p.V161= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- NKAIN3 | c.279C>T p.T93= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs148093471; called by muse, mutect2, varscan2
- NOS1 | c.462T>A p.G154= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- NSUN7 | c.759T>C p.F253= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- NTNG2 | c.630C>T p.H210= | Silent (SNP) | VAF 26/178 reads (15%) | called by muse, mutect2, varscan2
- ONECUT2 | c.1071G>A p.A357= | Silent (SNP) | VAF 35/263 reads (13%) | called by muse, mutect2, varscan2
- PLXNA3 | c.855C>T p.R285= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs192841912, COSV63754258; called by muse, mutect2, varscan2
- RPS6KA4 | c.2055C>G p.L685= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV53705901; called by muse, mutect2
- SLC45A4 | c.1233C>T p.S411= (on ENST00000517878 / NM_001286646.2; = p.S360= on NM_001080431.2) | Silent (SNP) | VAF 18/213 reads (8%) | called by muse, mutect2
- STAB2 | c.3561G>A p.R1187= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- TPD52L1 | c.315C>T p.H105= | Silent (SNP) | VAF 27/199 reads (14%) | catalogued as rs141489966; called by muse, mutect2, varscan2
- TSPOAP1 | c.4416T>A p.P1472= | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- TUBA4A | c.195A>T p.A65= | Silent (SNP) | VAF 40/376 reads (11%) | called by muse, mutect2, varscan2
- VPS4A | c.747G>C p.T249= | Silent (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- AC064805.2 | n.2460C>A | RNA (SNP) | VAF 19/146 reads (13%) | catalogued as rs1224500444; called by muse, mutect2, varscan2
- AL713998.1 | n.84T>A | RNA (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.384+8520G>A | Intron (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.*584A>G | 3'UTR (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- ARHGEF15 | c.*773C>A | 3'UTR (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- ARHGEF4 | c.1922-240C>T | Intron (SNP) | VAF 24/170 reads (14%) | catalogued as rs983459542; called by muse, mutect2, varscan2
- ATF4 | c.-494G>A | 5'UTR (SNP) | VAF 31/197 reads (16%) | catalogued as rs1364907772; called by muse, mutect2, varscan2
- ATP9A | c.*669A>T | 3'UTR (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- BCL2 | c.*1435G>T | 3'UTR (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- BCLAF1 | c.*162G>A | 3'UTR (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2, varscan2
- BRD1 | c.*299T>C | 3'UTR (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- C2orf50 | c.*351C>T | 3'UTR (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- CA12 | c.*3109T>A | 3'UTR (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- CALN1 | c.*1143C>T | 3'UTR (SNP) | VAF 31/140 reads (22%) | catalogued as rs375270448; called by muse, mutect2, varscan2
- CCDC34 | chr11:27363220 G>C | 5'Flank (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- CCDC50 | c.*3562A>G | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- CCDC6 | c.*643G>T | 3'UTR (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- CD300LD | c.*493C>A | 3'UTR (SNP) | VAF 12/47 reads (26%) | catalogued as rs1308231200; called by muse, mutect2, varscan2
- CDC42BPA | c.-123A>T | 5'UTR (SNP) | VAF 33/129 reads (26%) | called by muse, mutect2, varscan2
- CDH11 | c.*3198A>C | 3'UTR (SNP) | VAF 34/187 reads (18%) | called by muse, mutect2, varscan2
- COL19A1 | c.*1030G>A | 3'UTR (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- CREBZF | c.*1525A>T | 3'UTR (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1057-230382T>G | Intron (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- CWC22 | c.*210G>A | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- CYP19A1 | c.628+286C>T | Intron (SNP) | VAF 17/68 reads (25%) | catalogued as rs564101220; called by muse, mutect2, varscan2
- DIS3 | c.*2959T>C | 3'UTR (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- DOCK4 | c.5014-601T>C | Intron (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- EDARADD | c.*82A>T | 3'UTR (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- EPO | c.*512T>C | 3'UTR (SNP) | VAF 30/127 reads (24%) | called by muse, mutect2, varscan2
- EYS | c.1766+3418C>G | Intron (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- FAM189A2 | c.857-268C>T | Intron (SNP) | VAF 29/329 reads (9%) | called by muse, mutect2
- FGG | c.533-84C>A | Intron (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- FMN1 | c.*6057T>G | 3'UTR (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- GABRG1 | c.*542T>A | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- GALNT17 | c.-232G>T | 5'UTR (SNP) | VAF 18/251 reads (7%) | called by muse, mutect2
- GRTP1 | c.921+392C>T | Intron (SNP) | VAF 23/228 reads (10%) | catalogued as rs1227422877; called by muse, mutect2
- GUCA1B | c.*482A>G | 3'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as rs1390429063; called by muse, mutect2
- HABP2 | c.*919T>C | 3'UTR (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- HHLA1 | c.1469+1053G>C | Intron (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- HMCN1 | c.-5del | 5'UTR (DEL) | VAF 20/113 reads (18%) | catalogued as rs755887128; called by mutect2, varscan2
- HMGCL | n.359T>G | RNA (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2
- HOXB3 | chr17:48545537 C>T | 3'Flank (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2
- HSPA1B | c.-125G>C | 5'UTR (SNP) | VAF 13/485 reads (3%) | called by muse, mutect2
- IFI44 | c.*165A>C | 3'UTR (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- IL17RA | c.*5858A>C | 3'UTR (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- IPO4 | c.279-117A>G | Intron (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- IRX6 | c.-455C>T | 5'UTR (SNP) | VAF 31/191 reads (16%) | called by muse, mutect2, varscan2
- ISLR2 | c.*973C>T | 3'UTR (SNP) | VAF 29/171 reads (17%) | called by muse, mutect2, varscan2
- ITGA1 | c.*3401T>A | 3'UTR (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- ITPRID1 | chr7:31653045 A>T | 3'Flank (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- KCNK2 | c.-49C>T | 5'UTR (SNP) | VAF 78/683 reads (11%) | catalogued as rs1308925350, COSV67218698; called by muse, mutect2, varscan2
- KLHL1 | c.*118G>T | 3'UTR (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- KLHL14 | chr18:32773684 T>C | 5'Flank (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- LAMB2 | c.1890+35C>A | Intron (SNP) | VAF 18/205 reads (9%) | called by muse, mutect2
- LINC01565 | n.2309G>A | RNA (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- MAP2K3 | c.-52G>T | 5'UTR (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- MIR5195 | chr14:106851126 T>G | 5'Flank (SNP) | VAF 54/340 reads (16%) | catalogued as rs569234583; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851252 T>G | 5'Flank (SNP) | VAF 45/256 reads (18%) | catalogued as rs555046741; called by muse, mutect2, varscan2
- MMP16 | c.*618A>T | 3'UTR (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- MTMR12 | c.*469G>A | 3'UTR (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- MYLK | c.5239-2334T>G | Intron (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- NACC2 | c.*3244G>C | 3'UTR (SNP) | VAF 32/165 reads (19%) | called by muse, mutect2, varscan2
- NANOS1 | c.*2509_*2510del | 3'UTR (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel*, varscan2
- NFATC2 | c.*1533G>C | 3'UTR (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- NHS | c.*1601T>G | 3'UTR (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- NOC2LP1 | n.1107G>T | RNA (SNP) | VAF 21/141 reads (15%) | catalogued as rs1421020573; called by muse, mutect2, varscan2
- NPAS3 | c.385+154A>T | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- NRG3 | c.824-125935C>T | Intron (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2
- NTN4 | c.*193T>A | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- OR5B2 | c.*56C>A | 3'UTR (SNP) | VAF 18/214 reads (8%) | catalogued as rs1244128075; called by muse, mutect2
- OR6C74 | c.-59G>T | 5'UTR (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- OR6C74 | c.-58C>G | 5'UTR (SNP) | VAF 26/296 reads (9%) | called by muse, mutect2
- OTULIN | c.*5098A>C | 3'UTR (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2, varscan2
- PAPPA | c.*1332T>C | 3'UTR (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- PCSK9 | c.524-139T>G | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- PDE3A | c.*3930_*3946del | 3'UTR (DEL) | VAF 11/123 reads (9%) | called by mutect2, pindel
- PEG10 | c.*2616T>A | 3'UTR (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- PEX5 | chr12:7210345 C>T | 3'Flank (SNP) | VAF 9/108 reads (8%) | catalogued as rs760005244; called by muse, mutect2
- PLEKHG6 | c.138+505G>T | Intron (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- PLOD2 | c.*308T>G | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- PMEPA1 | c.*2892G>A | 3'UTR (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- PMPCA | c.*424G>A | 3'UTR (SNP) | VAF 31/135 reads (23%) | catalogued as rs555888715; called by muse, mutect2, varscan2
- POMC | chr2:25160917 G>A | 3'Flank (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- PPP1R14C | c.*389A>C | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- PRDM16 | c.*1602T>C | 3'UTR (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- PREB | c.-55C>T | 5'UTR (SNP) | VAF 7/116 reads (6%) | catalogued as rs1018862046; called by muse, mutect2
- PRSS58 | c.*59A>T | 3'UTR (SNP) | VAF 20/300 reads (7%) | called by muse, mutect2
- PSG7 | c.1244-138T>G | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.*774T>G | 3'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- RAB18 | c.*1964T>G | 3'UTR (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- RBFOX2 | c.*3276T>G | 3'UTR (SNP) | VAF 11/62 reads (18%) | catalogued as rs1324700988; called by muse, mutect2, varscan2
- RBM28 | c.*375G>C | 3'UTR (SNP) | VAF 12/88 reads (14%) | catalogued as rs369408365; called by muse, mutect2, varscan2
- RIMBP2 | c.*751T>G | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- RNF144B | c.*3185G>C | 3'UTR (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- RNF39 | c.*591T>C | 3'UTR (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- RSL24D1 | c.*1128A>G | 3'UTR (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- SART3 | c.*713G>A | 3'UTR (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- SCN11A | c.4327+304A>T | Intron (SNP) | VAF 31/112 reads (28%) | catalogued as COSV56573606; called by muse, mutect2, varscan2
- SELENOI | c.*5555A>T | 3'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as rs957267384, COSV53144323; called by muse, varscan2
- SEMA3A | c.*2900T>C | 3'UTR (SNP) | VAF 25/102 reads (25%) | catalogued as rs1036384401; called by muse, mutect2, varscan2
- SEMA3D | c.*153A>C | 3'UTR (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- SHTN1 | c.*3977G>A | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- SLC12A5 | c.121+16G>A | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- SLC22A9 | c.-53C>A | 5'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- SNPH | c.-47-294G>A | Intron (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- SPOCK1 | c.*1675C>A | 3'UTR (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- STAC2 | c.*491C>T | 3'UTR (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- TBXT | c.*532T>C | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2, varscan2
- TECPR2 | c.*3186A>G | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- TFAP2B | c.*167del | 3'UTR (DEL) | VAF 14/112 reads (13%) | catalogued as rs375026920; called by mutect2, varscan2
- TGFB3 | c.*242A>G | 3'UTR (SNP) | VAF 47/221 reads (21%) | called by muse, mutect2, varscan2
- TIFAB | c.*4689G>A | 3'UTR (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2, varscan2
- TMEM132B | c.*2130A>T | 3'UTR (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2
- TMSB4X | c.-37G>A | 5'UTR (SNP) | VAF 15/94 reads (16%) | catalogued as rs1232954174; called by muse, mutect2, varscan2
- TNF | c.-132G>T | 5'UTR (SNP) | VAF 64/671 reads (10%) | called by muse, mutect2
- TRIM23 | c.*1985G>A | 3'UTR (SNP) | VAF 17/101 reads (17%) | catalogued as rs954027660; called by muse, mutect2, varscan2
- TRIM29 | c.805-86C>T | Intron (SNP) | VAF 46/293 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+4501T>A | Intron (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- UFM1 | c.-57G>T | 5'UTR (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- URGCP | c.202+501A>G | Intron (SNP) | VAF 62/579 reads (11%) | called by muse, mutect2, varscan2
- WDR59 | c.*70G>A | 3'UTR (SNP) | VAF 32/209 reads (15%) | called by muse, mutect2, varscan2
- WHAMMP2 | chr15:28764120 C>T | 3'Flank (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- WHAMMP3 | chr15:22691129 C>T | 3'Flank (SNP) | VAF 8/173 reads (5%) | catalogued as rs1231856982; called by muse, mutect2
- YPEL4 | c.*49C>A | 3'UTR (SNP) | VAF 14/107 reads (13%) | catalogued as rs765322413; called by muse, mutect2, varscan2
- ZC3H6 | c.*3531G>A | 3'UTR (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- ZFAND4 | c.*182A>G | 3'UTR (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- ZFPM2 | c.-166C>A | 5'UTR (SNP) | VAF 35/251 reads (14%) | called by muse, mutect2, varscan2
- ZKSCAN1 | c.*593C>T | 3'UTR (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- ZNF346 | c.*244G>T | 3'UTR (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- ZNF514 | c.*152T>A | 3'UTR (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- ZNF527 | c.*2094G>C | 3'UTR (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- ZNF716 | c.*745A>T | 3'UTR (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
